Gene-level copy-number profile of tumor specimen TCGA-OR-A5L6-01A from TCGA case TCGA-OR-A5L6, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 60.4 years (22,057 days).
Specimen TCGA-OR-A5L6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.6f31f549-75a3-4c9d-a677-e294e868e4c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5L6-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7139d415-32dc-467d-88f3-b6854007f893

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,284; copy number 3: 16,830; copy number 4: 25,648; copy number 5: 408; copy number 6: 2,795; copy number 7: 1,855; copy number 8: 4,970; copy number 9: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5L6-01A-11D-A29H-01): tumor purity 0.8, ploidy 4, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 29 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:84,382,424–87,137,712, 29 genes, copy number 9 (within-gene range 8–9): EDIL3-DT, PPIAP79, AC114928.1, RBBP4P6, AC117522.3, AC117522.2, AC117522.1, AC010486.1, AC010486.2, AC010486.3, RPL5P17, AC026700.1, AC010595.1, RPS2P25, AC026414.1, PTP4A1P4, NBPF22P, AC020923.1, AC016550.1, AC016550.2, AC016550.3, AC026444.1, COX7C, SNORD138, RNU6-804P, LINC02059, AC008539.1, AC091429.1, AC109492.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
